Somatic mutation profile of tumor specimen TCGA-D1-A17D-01A (aliquot TCGA-D1-A17D-01A-12D-A12J-09) from TCGA case TCGA-D1-A17D, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 58.7 years (21,441 days).
Specimen TCGA-D1-A17D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22d82232-16fe-475d-b184-ba1d9fdb2c40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A17D-10A (Blood Derived Normal), aliquot TCGA-D1-A17D-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e459167d-5168-459e-b36c-6254b9e3a6ea

The open-access MAF lists 588 somatic variants for this specimen: 448 protein-altering or splice-affecting, 133 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 309, Silent 133, Frame Shift Del 87, Nonsense Mutation 17, Splice Site 13, Frame Shift Ins 9, Splice Region 6, In Frame Del 6, Intron 2, 5'Flank 2, 5'UTR 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 94/294 reads (32%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, varscan2
- CCND1 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57119846, COSV57120106, COSV57120715; called by muse, mutect2, varscan2
- CNTN1 | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 63/179 reads (35%) | catalogued as rs753826693, COSV61639215, COSV61640338; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL7A1 | c.6081del p.P2029Lfs*177 | Frame Shift Del (DEL) | VAF 15/34 reads (44%) | catalogued as rs780623622, CD961934; ClinVar: pathogenic; called by mutect2, varscan2
- KANSL1 | c.2899del p.Q967Sfs*46 (on ENST00000574590 / NM_001193465.2; = p.Q968Sfs*46 on NM_015443.4) | Frame Shift Del (DEL) | VAF 25/94 reads (27%) | catalogued as rs1374665357; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- LTBP3 | c.2216del p.G739Afs*7 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as rs752375653, CD153951; ClinVar: pathogenic; called by mutect2, pindel
- NDE1 | c.733del p.L245Sfs*26 (on ENST00000577101; = p.L245Sfs*113 on NM_017668.3) | Frame Shift Del (DEL) | VAF 33/92 reads (36%) | catalogued as rs749768828; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3R1 | c.1372_1374del p.E458del (on ENST00000521381 / NM_181523.3; = p.E188del on NM_181504.4) | In Frame Del (DEL) | VAF 11/49 reads (22%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 83/249 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.720C>G p.Y240* | Nonsense Mutation (SNP) | VAF 62/191 reads (32%) | catalogued as rs190070312, CM110218, COSV64290045, COSV64297643; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TJP2 | c.2209G>A p.G737S | Missense Mutation (SNP) | VAF 83/249 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139314808; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTLL5 | c.1435C>T p.R479* | Nonsense Mutation (SNP) | VAF 126/384 reads (33%) | catalogued as rs753018563, COSV54034914; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.2740G>C p.A914P | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.124); catalogued as COSV54030858; called by muse, mutect2, varscan2
- ABCA7 | c.3019C>T p.R1007C | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373517680; called by muse, mutect2, varscan2
- ABCA8 | c.3763G>T p.G1255C | Missense Mutation (SNP) | VAF 76/228 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV52202729, COSV52214811; called by muse, mutect2, varscan2
- ABCC2 | c.3212T>G p.F1071C | Missense Mutation (SNP) | VAF 99/234 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64986571; called by muse, mutect2, varscan2
- ACCS | c.476T>C p.L159P | Missense Mutation (SNP) | VAF 63/193 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55458529; called by muse, mutect2, varscan2
- ACLY | c.3287C>T p.P1096L | Missense Mutation (SNP) | VAF 68/206 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148640026; called by muse, mutect2, varscan2
- ACSL1 | c.724G>T p.G242W | Missense Mutation (SNP) | VAF 8/204 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55661049, COSV55666266; called by muse, mutect2
- ADAMTS13 | c.3656G>A p.R1219Q | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs782649881, CM161741, COSV52470280; called by muse, mutect2, varscan2
- ADAMTS9 | c.3814G>A p.V1272M | Missense Mutation (SNP) | VAF 64/199 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.067); catalogued as rs1478846671, COSV55782364; called by muse, mutect2, varscan2
- ADAMTS9 | c.2623A>G p.K875E | Missense Mutation (SNP) | VAF 74/188 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV55782377; called by muse, mutect2, varscan2
- ADRA1D | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV65240481; called by muse, mutect2, varscan2
- AMPH | c.1195T>A p.S399T | Missense Mutation (SNP) | VAF 75/226 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV57743682; called by muse, mutect2, varscan2
- AMY2B | c.1497G>T p.E499D | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.046); catalogued as COSV63715474, COSV63716278; called by muse, mutect2, varscan2
- ANK3 | c.11933C>G p.T3978S | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as COSV55060920, COSV99779017; called by muse, mutect2, varscan2
- ANTXR2 | c.428T>C p.I143T | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV55018809; called by muse, mutect2, varscan2
- AP2A2 | c.766T>C p.W256R | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59960744; called by muse, mutect2
- APOC4-APOC2 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT tolerated, low confidence (0.12); catalogued as COSV52990428; called by muse, mutect2, varscan2
- AQP3 | c.754C>A p.L252M | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as COSV53048453; called by muse, mutect2, varscan2
- ARFGEF3 | c.1582C>A p.H528N | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV52458982, COSV52466847; called by muse, mutect2, varscan2
- ARHGAP39 | c.2342G>T p.R781L | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52770982; called by muse, mutect2, varscan2
- ARHGAP6 | c.2187G>T p.E729D (on ENST00000337414 / NM_013427.3; = p.E526D on NM_013423.3) | Missense Mutation (SNP) | VAF 90/223 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.776); catalogued as COSV57296556; called by muse, mutect2, varscan2
- ARHGEF10 | c.3785C>A p.P1262H (on ENST00000398564; = p.P1237H on NM_014629.4) | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.168); catalogued as COSV50653193; called by muse, mutect2, varscan2
- ARHGEF7 | c.1673T>C p.V558A (on ENST00000375741 / NM_001113511.2; = p.V380A on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/197 reads (36%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.955); catalogued as COSV54539108; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 32/101 reads (32%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARID5B | c.1489del p.I497* | Frame Shift Del (DEL) | VAF 48/139 reads (35%) | catalogued as rs201178069; called by mutect2, pindel, varscan2
- ARL15 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 67/165 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.666); catalogued as COSV72290745; called by muse, mutect2, varscan2
- ARMC5 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.731); catalogued as COSV51656998; called by muse, mutect2, varscan2
- ARNTL | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 125/334 reads (37%) | catalogued as COSV62986912; called by muse, mutect2, varscan2
- ARPC1A | c.713+2T>C p.X238_splice | Splice Site (SNP) | VAF 64/177 reads (36%) | catalogued as COSV53557093; called by muse, mutect2, varscan2
- ATE1 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 77/251 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs535459996, COSV56437036; called by muse, mutect2, varscan2
- ATF5 | c.255del p.G86Afs*32 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | catalogued as rs766479650; called by mutect2, pindel, varscan2
- ATP11B | c.2650del p.Y884Ifs*30 | Frame Shift Del (DEL) | VAF 40/116 reads (34%) | catalogued as rs759638000; called by mutect2, varscan2
- ATP2B3 | c.3524del p.P1175Rfs*12 | Frame Shift Del (DEL) | VAF 30/54 reads (56%) | catalogued as rs782513834; called by mutect2, varscan2
- ATP6AP1 | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV63895768; called by muse, mutect2, varscan2
- ATP6V0A4 | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs539497353, COSV59475611; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1450+8T>C | Splice Region (SNP) | VAF 51/116 reads (44%) | catalogued as rs900458840, COSV57280070; called by muse, mutect2, varscan2
- BMP1 | c.2901del p.G968Vfs*37 | Frame Shift Del (DEL) | VAF 41/140 reads (29%) | catalogued as rs964719937; called by mutect2, pindel, varscan2
- BRPF1 | c.1867C>T p.Q623* | Nonsense Mutation (SNP) | VAF 52/160 reads (33%) | catalogued as COSV57405264; called by muse, mutect2, varscan2
- C19orf47 | c.1115G>A p.S372N | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV63509266; called by muse, mutect2, varscan2
- C6orf62 | c.242C>A p.S81Y | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV65290549; called by muse, mutect2
- CACNB1 | c.439G>C p.G147R | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59999033; called by muse, mutect2, varscan2
- CARHSP1 | c.281A>C p.D94A | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60683943; called by muse, mutect2, varscan2
- CASP5 | c.533del p.N178Ifs*8 | Frame Shift Del (DEL) | VAF 83/250 reads (33%) | catalogued as rs765105588; called by mutect2, varscan2
- CBX3 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 53/212 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.108); catalogued as COSV61761441; called by muse, mutect2, varscan2
- CBX4 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV53965880; called by muse, mutect2, varscan2
- CCL24 | c.128C>A p.P43H | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56116306; called by muse, mutect2, varscan2
- CCR8 | c.977T>C p.L326P | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as COSV58337328; called by muse, mutect2, varscan2
- CD40LG | c.328A>T p.S110C | Missense Mutation (SNP) | VAF 69/171 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.227); catalogued as COSV65698591; called by muse, mutect2, varscan2
- CECR2 | c.3157G>A p.G1053S (on ENST00000342247 / NM_001290047.2; = p.G869S on NM_001290046.1) | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs368828545; called by muse, mutect2, varscan2
- CELF2 | c.310C>T p.H104Y (on ENST00000416382 / NM_001025077.3; = p.H111Y on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 82/254 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59974893; called by muse, mutect2, varscan2
- CELF4 | c.1171G>A p.A391T | Missense Mutation (SNP) | VAF 66/171 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV58454572; called by muse, mutect2, varscan2
- CELSR1 | c.1847G>A p.S616N | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as COSV53091331; called by muse, mutect2, varscan2
- CELSR3 | c.7689C>G p.S2563R | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.699); catalogued as COSV50869974; called by muse, mutect2, varscan2
- CELSR3 | c.2338G>A p.A780T | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751054282, COSV50870133; called by muse, mutect2, varscan2
- CENPF | c.4704G>C p.E1568D | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.036); catalogued as COSV65272586, COSV65275449; called by muse, mutect2, varscan2
- CERCAM | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs1244088649, COSV65711130; called by muse, mutect2, varscan2
- CERS2 | c.149T>G p.L50R | Missense Mutation (SNP) | VAF 69/224 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV54984040; called by muse, mutect2, varscan2
- CFAP74 | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.516); catalogued as COSV54568579; called by muse, mutect2, varscan2
- CHFR | c.1403C>T p.T468M (on ENST00000432561 / NM_001161345.1; = p.T427M on NM_018223.2) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.724); catalogued as rs752333209, COSV57174936; called by muse, mutect2, varscan2
- CLGN | c.1522del p.T508Pfs*12 | Frame Shift Del (DEL) | VAF 55/160 reads (34%) | catalogued as rs1217577246; called by mutect2, pindel, varscan2
- CLIP3 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs553572365, COSV62111734; called by muse, mutect2, varscan2
- COIL | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53595181; called by muse, mutect2, varscan2
- COL27A1 | c.352C>A p.R118S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.127); catalogued as COSV61921043, COSV61926792; called by muse, mutect2, varscan2
- COX19 | c.186G>T p.R62S | Missense Mutation (SNP) | VAF 85/258 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59937594; called by muse, mutect2, varscan2
- CPT1C | c.2194C>A p.H732N | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54919661; called by muse, mutect2, varscan2
- CRACDL | c.373C>T p.Q125* | Nonsense Mutation (SNP) | VAF 16/200 reads (8%) | catalogued as COSV67408388; called by muse, mutect2
- CTBP1 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.762); catalogued as COSV52074413; called by muse, mutect2, varscan2
- CTCF | c.1544G>A p.R515H | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV50471057; called by muse, mutect2, varscan2
- CTNNA3 | c.1059dup p.E354Rfs*4 | Frame Shift Ins (INS) | VAF 58/192 reads (30%) | catalogued as rs1351207870; called by mutect2, varscan2
- CTPS1 | c.1126C>T p.R376* | Nonsense Mutation (SNP) | VAF 127/350 reads (36%) | catalogued as COSV65452748; called by muse, mutect2, varscan2
- CTPS2 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 74/180 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63722807; called by muse, mutect2, varscan2
- CUX2 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.081); catalogued as rs1488002704, COSV55634457; called by muse, mutect2, varscan2
- CYP2A13 | c.345C>T p.G115= | Splice Region (SNP) | VAF 8/16 reads (50%) | catalogued as COSV57838153; called by muse, mutect2, varscan2
- DCAF6 | c.2498C>T p.S833L (on ENST00000312263 / NM_001349778.1; = p.S853L on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as COSV56579475; called by muse, mutect2, varscan2
- DCAF7 | c.775G>A p.V259I | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as COSV60407716; called by muse, mutect2, varscan2
- DCC | c.3691del p.R1231Gfs*5 | Frame Shift Del (DEL) | VAF 73/182 reads (40%) | catalogued as rs1568151221; called by mutect2, pindel, varscan2
- DCDC2 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 24/350 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs771591530, COSV65829013; ClinVar: uncertain significance; called by muse, mutect2
- DCLK3 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 23/223 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.652); catalogued as rs560482238, COSV69363344; called by muse, mutect2, varscan2
- DCP2 | c.809G>T p.R270L | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.392); catalogued as COSV66616890, COSV66617162; called by muse, mutect2, varscan2
- DDX49 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs753844299, COSV53229994; called by muse, mutect2, varscan2
- DGKK | c.1709A>G p.Q570R | Missense Mutation (SNP) | VAF 95/246 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as COSV65707742; called by muse, mutect2, varscan2
- DHX58 | c.1502C>T p.T501M | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.168); catalogued as rs188650103; called by muse, mutect2, varscan2
- DIPK1B | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as rs369842977; called by muse, varscan2
- DIS3L2 | c.745G>A p.G249S | Missense Mutation (SNP) | VAF 100/283 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs985913473, COSV56052519; called by muse, mutect2, varscan2
- DLG2 | c.754A>G p.S252G | Missense Mutation (SNP) | VAF 80/350 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as rs777781126, COSV54649554; called by muse, mutect2, varscan2
- DLX3 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV71547680; called by muse, mutect2, varscan2
- DMPK | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs781436323, COSV52178867; called by muse, mutect2, varscan2
- DNA2 | c.2326C>T p.L776F | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753597233, COSV64428742; called by muse, varscan2
- DPH5 | c.476C>T p.T159I | Missense Mutation (SNP) | VAF 73/237 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59859627; called by muse, mutect2, varscan2
- DSCC1 | c.53A>T p.N18I | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV58087298; called by muse, mutect2, varscan2
- DST | c.9505G>A p.A3169T | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.007); catalogued as COSV55018264; called by muse, mutect2, varscan2
- DTNB | c.1729G>A p.A577T | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs762841562, COSV56477867; called by muse, mutect2, varscan2
- EBF1 | c.1333G>A p.V445M | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.739); catalogued as rs1306966109, COSV58166318; called by muse, mutect2, varscan2
- EHD3 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs769119216, COSV59031053; called by muse, mutect2, varscan2
- EIF3J | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV56008930; called by muse, mutect2, varscan2
- ENPP7 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as rs782178230, COSV60385205; called by muse, mutect2, varscan2
- EP400 | c.6063+2T>C p.X2021_splice | Splice Site (SNP) | VAF 57/166 reads (34%) | catalogued as COSV57774123; called by muse, mutect2, varscan2
- ERCC6L | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 67/188 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.215); catalogued as rs1157150843, COSV57820025; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 64/143 reads (45%) | catalogued as rs775950025; called by mutect2, varscan2
- ETV1 | c.414dup p.T139Hfs*24 | Frame Shift Ins (INS) | VAF 94/316 reads (30%) | catalogued as rs769886672; called by mutect2, varscan2
- EXOC6 | c.541A>G p.M181V | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs1238327186, COSV53325415; called by muse, mutect2, varscan2
- EZH1 | c.426A>T p.E142D | Missense Mutation (SNP) | VAF 155/427 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as COSV70549548; called by muse, mutect2, varscan2
- F5 | c.693G>A p.M231I | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.867); catalogued as COSV63124717; called by muse, mutect2, varscan2
- FAM163A | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 63/185 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1193267004, COSV59203867; called by muse, mutect2, varscan2
- FAM200A | c.1094del p.N365Tfs*12 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as rs1268664972; called by mutect2, pindel, varscan2
- FAM221B | c.519G>T p.E173D | Missense Mutation (SNP) | VAF 44/522 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV65074455; called by muse, mutect2
- FAM78B | c.55G>A p.V19M | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.325); catalogued as rs771748940, COSV57977890; called by muse, mutect2, varscan2
- FAM83E | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.24); catalogued as rs1050702319, COSV50031824; called by muse, mutect2, varscan2
- FCN3 | c.158C>A p.P53H | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV54641352, COSV54641530; called by muse, mutect2, varscan2
- FCRL3 | c.814del p.R272Gfs*3 | Frame Shift Del (DEL) | VAF 70/212 reads (33%) | catalogued as rs1288807478; called by mutect2, varscan2
- FHDC1 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199815161; called by muse, mutect2, varscan2
- FLNA | c.5874G>A p.M1958I (on ENST00000369850 / NM_001110556.2; = p.M1950I on NM_001456.3) | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100774330, COSV61042951; called by muse, mutect2
- FLNA | c.5872A>T p.M1958L (on ENST00000369850 / NM_001110556.2; = p.M1950L on NM_001456.3) | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1569551491, COSV61044197; ClinVar: uncertain significance; called by muse, mutect2
- FMNL3 | c.1886C>T p.A629V | Missense Mutation (SNP) | VAF 135/365 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs749938194, COSV53302752; called by muse, mutect2, varscan2
- FN1 | c.1965G>T p.K655N | Missense Mutation (SNP) | VAF 108/286 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV60554499; called by muse, mutect2, varscan2
- FOSL2 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1474485068, COSV53103721; called by muse, mutect2, varscan2
- FOXG1 | c.1394C>T p.T465M | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV57397112; called by muse, mutect2, varscan2
- FOXRED1 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 125/396 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs535066892, COSV55007002; called by muse, mutect2, varscan2
- FSIP2 | c.18415A>G p.T6139A | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.683); catalogued as COSV58087893; called by muse, mutect2, varscan2
- FYCO1 | c.3550C>T p.R1184W | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs760469053, COSV56116467; called by muse, mutect2, varscan2
- G3BP1 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.425); catalogued as COSV62365924, COSV62366219; called by muse, mutect2, varscan2
- G3BP2 | c.637G>C p.V213L | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as COSV62976501; called by muse, mutect2
- GAL3ST1 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as rs1438236258, COSV58892750; called by muse, mutect2, varscan2
- GATA1 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV64962318; called by muse, mutect2, varscan2
- GCDH | c.1123T>C p.C375R | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1348974766, CM980877, COSV53366812; called by muse, mutect2, varscan2
- GCHFR | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.112); catalogued as COSV53066628; called by muse, mutect2, varscan2
- GJB4 | c.123G>T p.E41D | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58356310; called by muse, mutect2, varscan2
- GMIP | c.2776C>T p.R926C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs747941391, COSV52556768; called by muse, mutect2, varscan2
- GON4L | c.2861G>A p.R954Q | Missense Mutation (SNP) | VAF 111/315 reads (35%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs1476453021, COSV55194880; called by muse, mutect2, varscan2
- GPR153 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV64938607; called by muse, mutect2, varscan2
- GPS1 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57649346; called by muse, mutect2, varscan2
- GSTCD | c.1735G>A p.V579I (on ENST00000360505 / NM_001031720.3; = p.V492I on NM_024751.3) | Missense Mutation (SNP) | VAF 129/353 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.108); catalogued as rs766013167, COSV64733641; called by muse, mutect2, varscan2
- GXYLT2 | c.1330T>C p.*444Rext*13 | Nonstop Mutation (SNP) | VAF 62/165 reads (38%) | catalogued as COSV67474270; called by muse, mutect2, varscan2
- H1-0 | c.138_140del p.R47del | In Frame Del (DEL) | VAF 28/81 reads (35%) | catalogued as COSV50649112; called by mutect2, pindel, varscan2
- H2BC17 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58152831; called by muse, mutect2, varscan2
- HAS3 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs896758135, COSV54706444; called by muse, mutect2, varscan2
- HCN2 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM147956, COSV52115104; called by muse, mutect2, varscan2
- HCN4 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs918783630, COSV56083965; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HDAC3 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs771453225, COSV59496100; called by muse, mutect2, varscan2
- HELZ | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 26/336 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV62378790; called by muse, mutect2
- HELZ2 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as rs561374507, COSV64409765; called by mutect2, varscan2
- HMGCS2 | c.685G>T p.G229W | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65568090; called by muse, mutect2, varscan2
- HOXA11 | c.895del p.I299Lfs*30 | Frame Shift Del (DEL) | VAF 35/89 reads (39%) | catalogued as rs777829525; called by mutect2, varscan2
- HSPA12A | c.1528G>A p.V510M | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.843); catalogued as rs782554418, COSV65022528; called by muse, mutect2, varscan2
- IFI16 | c.611C>A p.P204Q | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55534822; called by muse, mutect2, varscan2
- IGHV4-28 | c.100T>C p.S34P | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.139); catalogued as rs1296451832; called by muse, varscan2
- IGSF21 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.078); catalogued as COSV52125877, COSV52134646, COSV52147493; called by muse, mutect2, varscan2
- IMMT | c.2029C>T p.P677S | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.983); catalogued as COSV54480552; called by muse, mutect2, varscan2
- INTS1 | c.4791del p.K1598Sfs*21 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | catalogued as rs1562490038; called by mutect2, pindel, varscan2
- IRAG1 | c.1999C>T p.R667C | Missense Mutation (SNP) | VAF 74/177 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766837084, COSV70211275; called by muse, mutect2, varscan2
- IRAG2 | c.4069C>T p.P1357S (on ENST00000636465; = p.P402S on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.237); catalogued as COSV57232633; called by muse, mutect2, varscan2
- ITGA6 | c.3351del p.K1117Nfs*? (on ENST00000442250; = p.K1078Nfs*48 on NM_001079818.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 30/118 reads (25%) | catalogued as rs201055917; ClinVar: uncertain significance; called by mutect2, varscan2
- ITPR1 | c.5051C>T p.T1684I (on ENST00000354582; = p.T1669I on NM_002222.7) | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.419); catalogued as rs1202494098, COSV56984409; called by muse, mutect2, varscan2
- ITPR3 | c.1781C>T p.T594I | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV65410241; called by muse, mutect2, varscan2
- JARID2 | c.2621G>A p.G874D | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs752539694, COSV59190448; called by muse, mutect2, varscan2
- KCNA5 | c.398C>G p.T133R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52906401, COSV99364165; called by muse, mutect2, varscan2
- KCNK15 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as rs1379093312, COSV65719796; called by muse, mutect2, varscan2
- KCNMB2 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1485740733, COSV64201075; called by muse, mutect2, varscan2
- KDM4A | c.2474G>A p.R825H | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1462901601, COSV64959739; called by muse, mutect2, varscan2
- KDM5A | c.3597del p.G1200Dfs*9 | Frame Shift Del (DEL) | VAF 88/219 reads (40%) | catalogued as rs771545848; called by mutect2, varscan2
- KIF23 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as rs756964640, COSV52980273; called by muse, mutect2, varscan2
- KLHL18 | c.1070A>G p.N357S | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs746259954, COSV51746054; called by muse, mutect2, varscan2
- KLHL34 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65279499; called by muse, mutect2, varscan2
- KMT2B | c.4949C>T p.T1650M | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555731828, COSV55860020; ClinVar: uncertain significance; called by muse, mutect2
- KRTAP10-4 | c.983G>A p.C328Y | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as rs1555923559, COSV59964829; called by muse, mutect2, varscan2
- KRTAP12-2 | c.377G>A p.C126Y | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.228); catalogued as COSV59964838; called by muse, mutect2, varscan2
- LAIR1 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV57307886; called by muse, mutect2, varscan2
- LAMA5 | c.3347C>T p.A1116V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as COSV53361296; called by muse, mutect2, varscan2
- LAMB2 | c.1204C>T p.R402W | Missense Mutation (SNP) | VAF 59/172 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757136658, COSV59734116; called by muse, mutect2, varscan2
- LARP1B | c.1075G>T p.G359C | Missense Mutation (SNP) | VAF 58/201 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs758314077, COSV52798179; called by muse, mutect2, varscan2
- LCOR | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1389391241, COSV63631089; called by muse, mutect2, varscan2
- LDB3 | c.59del p.G20Afs*41 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | catalogued as rs1308589918; called by mutect2, pindel, varscan2
- LFNG | c.1123C>A p.R375S (on ENST00000222725 / NM_001040167.2; = p.R246S on NM_002304.2) | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as COSV56069552; called by muse, mutect2, varscan2
- LGALS3BP | c.1670C>T p.S557F | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.99); catalogued as rs973119032, COSV53165152; called by muse, mutect2, varscan2
- LIMK2 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs755482329, COSV59182773; called by muse, mutect2, varscan2
- LINS1 | c.271C>A p.L91I | Missense Mutation (SNP) | VAF 66/218 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59079338; called by muse, mutect2, varscan2
- LRP1 | c.2327C>A p.P776H | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV54513465; called by muse, mutect2, varscan2
- LRP1 | c.13315G>A p.G4439R | Missense Mutation (SNP) | VAF 160/526 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.324); catalogued as rs764160826, COSV54506226; called by muse, mutect2, varscan2
- LRP5 | c.2194C>A p.L732I | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.352); catalogued as COSV53716747; called by muse, mutect2, varscan2
- LRRC4 | c.671A>G p.E224G | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV50814270; called by muse, mutect2, varscan2
- LRRN3 | c.12G>A p.M4I | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs372209557; called by muse, mutect2, varscan2
- MAD1L1 | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs771673407, COSV56231308; called by muse, mutect2, varscan2
- MADD | c.4713G>A p.M1571I | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV60624823; called by muse, mutect2, varscan2
- MAGI1 | c.1711A>G p.T571A | Missense Mutation (SNP) | VAF 93/279 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.151); catalogued as rs779140386, COSV58329047; called by muse, mutect2, varscan2
- MAML2 | c.1542G>A p.M514I | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs779962894, COSV73263656; called by muse, mutect2, varscan2
- MAMLD1 | c.885dup p.P297Tfs*82 | Frame Shift Ins (INS) | VAF 11/41 reads (27%) | catalogued as rs1468063437; called by mutect2, pindel, varscan2
- MANBA | c.824T>C p.V275A | Missense Mutation (SNP) | VAF 25/307 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.72); catalogued as COSV56965818; called by muse, mutect2
- MAP2K4 | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 79/237 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs775475276, COSV62257672; called by muse, varscan2
- MARF1 | c.832-1G>A p.X278_splice | Splice Site (SNP) | VAF 153/444 reads (34%) | catalogued as COSV60024285; called by muse, mutect2, varscan2
- MAST4 | c.6586C>G p.P2196A (on ENST00000403625 / NM_001164664.2; = p.P2007A on NM_015183.3) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as COSV55127781; called by muse, mutect2
- MAZ | c.1150C>T p.H384Y | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50715276; called by muse, mutect2, varscan2
- MC3R | c.835G>T p.A279S | Missense Mutation (SNP) | VAF 101/408 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.068); catalogued as COSV54763911; called by muse, mutect2, varscan2
- MECP2 | c.755G>A p.G252D | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CD041920, COSV57654259; called by muse, mutect2, varscan2
- MIB2 | c.416G>A p.G139D | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.957); catalogued as rs1266330523, COSV61755941; called by muse, mutect2, varscan2
- MICAL2 | c.948+1G>T p.X316_splice | Splice Site (SNP) | VAF 45/137 reads (33%) | catalogued as rs754758130, COSV56320971; called by muse, mutect2, varscan2
- MMP28 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.316); catalogued as rs367820262; called by muse, mutect2
- MMS22L | c.2485C>A p.L829I | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.127); catalogued as COSV51521731; called by muse, mutect2, varscan2
- MRGPRE | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs751476188, COSV67745749; called by muse, mutect2, varscan2
- MRPL45 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as rs550031536; called by muse, mutect2, varscan2
- MTMR2 | c.1845G>C p.Q615H | Missense Mutation (SNP) | VAF 103/272 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV57688853; called by muse, mutect2, varscan2
- MTUS2 | c.3250G>T p.D1084Y (on ENST00000612955 / NM_001366650.1; = p.D63Y on NM_015233.6) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV60158234; called by muse, mutect2, varscan2
- MYH1 | c.3744C>G p.N1248K | Missense Mutation (SNP) | VAF 106/312 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as COSV56849609; called by muse, mutect2, varscan2
- MYH14 | c.4342G>A p.D1448N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1407925871, COSV51820024; called by muse, mutect2, varscan2
- MYO10 | c.3667G>A p.G1223R | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434873123, COSV57016082, COSV57017061; called by muse, mutect2, varscan2
- MYOD1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51453801; called by mutect2, varscan2
- NADK | c.929C>T p.T310M | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1270606632, COSV58272857; called by muse, mutect2, varscan2
- NAPRT | c.1290C>T p.D430= | Splice Region (SNP) | VAF 19/57 reads (33%) | catalogued as rs371481966; called by muse, mutect2, varscan2
- NAV2 | c.6119T>A p.I2040N (on ENST00000396087 / NM_001244963.2; = p.I1981N on NM_145117.5) | Missense Mutation (SNP) | VAF 160/471 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60659982; called by muse, mutect2, varscan2
- NBN | c.2219C>T p.A740V | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554554240, COSV55373431; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEK1 | c.3698A>G p.N1233S | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs1242417137, COSV71456337; called by muse, mutect2, varscan2
- NEUROD4 | c.779G>A p.S260N | Missense Mutation (SNP) | VAF 71/190 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.254); catalogued as rs745732402, COSV54472017; called by muse, mutect2, varscan2
- NFE2L3 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs752395884, COSV50229363; called by muse, mutect2, varscan2
- NIBAN2 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs749689723, COSV64824510; called by muse, mutect2, varscan2
- NKAP | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV65056278; called by muse, mutect2, varscan2
- NKRF | c.1715C>A p.S572Y | Missense Mutation (SNP) | VAF 75/234 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV58661305, COSV58661758; called by muse, mutect2, varscan2
- NLRP1 | c.3778C>T p.R1260W | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs747487022, COSV52561169; called by muse, mutect2, varscan2
- NMT2 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781776823, COSV65382309; called by muse, mutect2, varscan2
- NONO | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV52137965; called by muse, mutect2, varscan2
- NPPA | c.16A>T p.T6S | Missense Mutation (SNP) | VAF 25/239 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV56740489; called by muse, mutect2, varscan2
- NRN1L | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1161334361, COSV59302837; called by muse, mutect2, varscan2
- NTRK1 | c.1426C>A p.L476M | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.77); catalogued as COSV62325991; called by muse, mutect2, varscan2
- NUDT6 | c.741G>C p.E247D | Missense Mutation (SNP) | VAF 68/235 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV52650395; called by muse, mutect2, varscan2
- OCEL1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs368314653, COSV52243904; called by muse, mutect2, varscan2
- OR5T1 | c.962G>A p.W321* | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | catalogued as COSV57302966; called by muse, mutect2, varscan2
- OSBP | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs748966536, COSV55662745; called by muse, mutect2, varscan2
- OSGIN2 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750953355, COSV52408294; called by muse, mutect2, varscan2
- PARP10 | c.2314C>A p.R772S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.07); catalogued as COSV100478113, COSV57298056; called by muse, mutect2
- PCARE | c.1727del p.P576Qfs*6 | Frame Shift Del (DEL) | VAF 21/69 reads (30%) | catalogued as rs1341882335; called by mutect2, pindel, varscan2
- PCDH10 | c.1901G>A p.R634H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.998); catalogued as COSV52095618; called by mutect2, varscan2
- PCDHAC1 | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV53846246, COSV53852350; called by muse, mutect2, varscan2
- PCDHB13 | c.1214C>T p.T405M | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1415617021, COSV53393124; called by muse, mutect2, varscan2
- PCDHGA4 | c.1543A>T p.N515Y | Missense Mutation (SNP) | VAF 82/220 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53960645; called by muse, mutect2, varscan2
- PCDHGB1 | c.1664C>T p.A555V | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.288); catalogued as COSV53960637; called by muse, mutect2, varscan2
- PCNX2 | c.6121G>A p.A2041T | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs374424345; called by muse, mutect2, varscan2
- PDE7A | c.1179del p.K393Nfs*6 (on ENST00000401827 / NM_001242318.3; = p.K367Nfs*6 on NM_002603.4) | Frame Shift Del (DEL) | VAF 23/80 reads (29%) | catalogued as rs776556726; called by mutect2, varscan2
- PDZD2 | c.8057A>G p.N2686S | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV56859921; called by muse, mutect2, varscan2
- PEPD | c.625-2A>G p.X209_splice | Splice Site (SNP) | VAF 26/343 reads (8%) | catalogued as COSV54891027; called by muse, mutect2
- PFKL | c.2304del p.H768Qfs*2 | Frame Shift Del (DEL) | VAF 11/24 reads (46%) | catalogued as COSV57394741; called by mutect2, varscan2
- PHF20L1 | c.229G>T p.G77W | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); catalogued as COSV55193432; called by muse, mutect2, varscan2
- PHLDB1 | c.3560G>A p.R1187H | Missense Mutation (SNP) | VAF 102/273 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs782000739, COSV61879079; called by muse, mutect2, varscan2
- PI4KA | c.908C>T p.T303I | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV55412588; called by muse, mutect2, varscan2
- PJA1 | c.1838G>A p.C613Y (on ENST00000361478 / NM_145119.4; = p.C425Y on NM_022368.5) | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64053272; called by muse, mutect2, varscan2
- PKD2L1 | c.665G>A p.S222N | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV58396349; called by muse, mutect2, varscan2
- PLA2G6 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.712); catalogued as rs1301929071, COSV59270148; called by muse, mutect2, varscan2
- PLAAT4 | c.483del p.A162Rfs*56 | Frame Shift Del (DEL) | VAF 50/143 reads (35%) | catalogued as rs745860467; called by mutect2, varscan2
- PLD1 | c.2782G>A p.A928T | Missense Mutation (SNP) | VAF 81/250 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV60568601; called by muse, mutect2, varscan2
- PLEKHA7 | c.2405del p.F802Sfs*21 | Frame Shift Del (DEL) | VAF 25/244 reads (10%) | catalogued as rs1333390805, COSV63043367; called by mutect2, varscan2
- PLEKHG5 | c.359T>C p.L120P (on ENST00000400915 / NM_001042663.3; = p.L83P on NM_020631.6) | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61702470; called by muse, mutect2, varscan2
- PLXNB3 | c.4963del p.V1655Cfs*7 | Frame Shift Del (DEL) | VAF 15/36 reads (42%) | catalogued as rs782076287; called by mutect2, varscan2
- POLD1 | c.462T>C p.P154= | Splice Region (SNP) | VAF 33/105 reads (31%) | catalogued as rs1019022551, COSV70955399; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLD1 | c.1816C>G p.L606V | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV70955405; called by muse, mutect2, varscan2
- PPM1A | c.835-1G>T p.X279_splice | Splice Site (SNP) | VAF 53/133 reads (40%) | catalogued as COSV57787067; called by muse, mutect2, varscan2
- PPP1R13B | c.2470G>A p.V824M | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.186); catalogued as rs769879634, COSV52452131; called by muse, mutect2, varscan2
- PPP1R13L | c.2068G>A p.D690N | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs375921349; called by muse, mutect2, varscan2
- PPP1R21 | c.2159C>T p.A720V (on ENST00000294952 / NM_001135629.3; = p.A709V on NM_152994.5) | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV54285156; called by muse, mutect2, varscan2
- PPP6R3 | c.1381C>A p.L461I (on ENST00000393800 / NM_001352375.2; = p.L410I on NM_018312.5) | Missense Mutation (SNP) | VAF 73/201 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55727757; called by muse, mutect2, varscan2
- PRAME | c.133C>A p.L45M | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101287005, COSV67161690; called by muse, mutect2, varscan2
- PRG4 | c.3090del p.K1030Nfs*14 | Frame Shift Del (DEL) | VAF 107/329 reads (33%) | catalogued as rs746925439; called by mutect2, pindel, varscan2
- PRKN | c.986del p.G329Afs*106 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | catalogued as COSV58292211; called by mutect2, pindel, varscan2
- PRPF40A | c.2138A>C p.K713T | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV68357766; called by muse, mutect2, varscan2
- PRR14L | c.6138G>T p.E2046D | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57884898; called by muse, mutect2, varscan2
- PSME3IP1 | c.447G>T p.Q149H | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV58429111, COSV58429398; called by muse, mutect2, varscan2
- PTPRT | c.341G>A p.R114K | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV100629312, COSV61960741; called by muse, mutect2, varscan2
- PTX3 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs564774580, COSV55821711; called by muse, mutect2, varscan2
- PXYLP1 | c.1435G>T p.G479* | Nonsense Mutation (SNP) | VAF 25/66 reads (38%) | catalogued as COSV53890899; called by muse, mutect2, varscan2
- RAB3D | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV55791548; called by muse, mutect2, varscan2
- RASGRP2 | c.1174-1G>A p.X392_splice | Splice Site (SNP) | VAF 60/181 reads (33%) | catalogued as COSV62449673; called by muse, mutect2, varscan2
- RERE | c.1760G>T p.G587V | Missense Mutation (SNP) | VAF 69/161 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV61943085; called by muse, mutect2, varscan2
- RGL4 | c.883G>A p.V295M | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764487860, COSV51944015; called by muse, mutect2, varscan2
- RIMS2 | c.1420del p.M474Wfs*5 (on ENST00000666250 / NM_001348490.2; = p.M282Wfs*5 on NM_014677.5 and 7 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 47/148 reads (32%) | catalogued as COSV99213901; called by mutect2, pindel, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 53/101 reads (52%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- ROCK2 | c.2932C>A p.L978I | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV59958081; called by muse, mutect2, varscan2
- RPGRIP1L | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770098954, COSV50906481; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 35/130 reads (27%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS6 | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 37/94 reads (39%) | catalogued as rs780806374, COSV59547728; called by muse, mutect2, varscan2
- RRP12 | c.139+1G>A p.X47_splice | Splice Site (SNP) | VAF 20/58 reads (34%) | catalogued as COSV59668063; called by muse, mutect2, varscan2
- RSRC1 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV55829938; called by muse, mutect2, varscan2
- RTN4RL1 | c.20G>A p.C7Y | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751646002, COSV58675824; called by muse, mutect2, varscan2
- RYR3 | c.4505G>A p.R1502H | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs545597409, COSV66776396, COSV66792288; called by muse, mutect2, varscan2
- RYR3 | c.10420T>C p.W3474R (on ENST00000389232; = p.W3475R on NM_001036.6) | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.736); catalogued as COSV66792294; called by muse, mutect2, varscan2
- SBDS | c.583A>G p.K195E | Missense Mutation (SNP) | VAF 156/454 reads (34%) | SIFT tolerated (0.74); PolyPhen benign (0.115); catalogued as COSV55887769; called by muse, mutect2, varscan2
- SCN10A | c.3529G>T p.D1177Y | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV71861708; called by muse, mutect2, varscan2
- SCN8A | c.5596C>T p.R1866W | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61978562; called by muse, mutect2, varscan2
- SENP1 | c.1227del p.G410Vfs*4 | Frame Shift Del (DEL) | VAF 45/180 reads (25%) | catalogued as rs750651342; called by mutect2, varscan2
- SERHL2 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 94/305 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs139740162; called by muse, varscan2
- SERPINE1 | c.283G>C p.A95P | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.112); catalogued as COSV56169760, COSV56169835; called by mutect2, varscan2
- SETDB1 | c.2849del p.P950Qfs*16 | Frame Shift Del (DEL) | VAF 72/255 reads (28%) | catalogued as rs1220025296; called by mutect2, pindel, varscan2
- SETX | c.6661C>T p.Q2221* | Nonsense Mutation (SNP) | VAF 10/188 reads (5%) | catalogued as COSV56386743; called by muse, mutect2
- SHROOM4 | c.3330G>T p.E1110D | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV56790235; called by muse, mutect2, varscan2
- SIPA1L1 | c.4364A>T p.Q1455L | Missense Mutation (SNP) | VAF 14/364 reads (4%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.775); catalogued as COSV62170645; called by muse, mutect2
- SLC15A4 | c.734G>A p.S245N | Missense Mutation (SNP) | VAF 79/209 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV57161742; called by muse, mutect2, varscan2
- SLC22A3 | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 14/197 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1049959110, COSV51712422; called by muse, mutect2
- SLC2A9 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as COSV53321728; called by muse, mutect2, varscan2
- SLC4A4 | c.2308G>A p.V770I (on ENST00000264485 / NM_001098484.3; = p.V726I on NM_003759.4) | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT tolerated (0.8); PolyPhen benign (0.104); catalogued as rs150967020, COSV52623703; called by muse, mutect2, varscan2
- SLC6A13 | c.1741G>A p.G581R | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs751271912, COSV58257565; called by muse, mutect2, varscan2
- SLC9B1 | c.353C>A p.P118H | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56470722; called by muse, mutect2, varscan2
- SLX4 | c.3401C>T p.S1134L | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1433489753, COSV53564636; called by muse, mutect2
- SMARCA4 | c.4090G>A p.E1364K | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV100759140, COSV60796160; called by muse, mutect2, varscan2
- SMC4 | c.1174C>T p.Q392* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV61005480; called by muse, mutect2, varscan2
- SMG7 | c.2720C>A p.P907H | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); catalogued as COSV61631660; called by muse, mutect2, varscan2
- SMOX | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as rs145014650, COSV53864664, COSV53865394; called by muse, mutect2, varscan2
- SOBP | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.96); catalogued as COSV57998638; called by muse, mutect2, varscan2
- SORBS2 | c.2668G>A p.V890I (on ENST00000284776 / NM_021069.5; = p.V456I on NM_003603.6) | Missense Mutation (SNP) | VAF 64/246 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.557); catalogued as COSV53002095; called by muse, mutect2, varscan2
- SOWAHB | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs774599059, COSV57554605; called by muse, mutect2, varscan2
- SP140 | c.408A>G p.V136= | Splice Region (SNP) | VAF 69/277 reads (25%) | catalogued as COSV59450529; called by muse, mutect2, varscan2
- SPHKAP | c.959C>T p.T320I | Missense Mutation (SNP) | VAF 32/345 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV60881355; called by muse, mutect2
- SPIRE1 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 23/261 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770657469, COSV59154315; called by muse, mutect2
- SPOP | c.208C>T p.R70* | Nonsense Mutation (SNP) | VAF 36/113 reads (32%) | catalogued as COSV61654194; called by muse, mutect2, varscan2
- SPOP | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV61652768; called by muse, mutect2, varscan2
- SPX | c.7-2A>G p.X3_splice | Splice Site (SNP) | VAF 97/275 reads (35%) | catalogued as COSV57020921; called by muse, mutect2, varscan2
- SRSF9 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 123/381 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV57570535; called by muse, mutect2, varscan2
- ST14 | c.1160T>C p.L387P | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV53833745; called by muse, mutect2, varscan2
- STAB1 | c.4015del p.V1339Cfs*252 | Frame Shift Del (DEL) | VAF 27/73 reads (37%) | catalogued as rs761841917, COSV100402435; called by mutect2, pindel, varscan2
- STAU2 | c.872G>A p.R291H (on ENST00000524300 / NM_001164380.2; = p.R259H on NM_014393.2) | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs749339080, COSV63307155; called by muse, mutect2, varscan2
- STK11IP | c.1835C>A p.P612H | Missense Mutation (SNP) | VAF 68/222 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55250357; called by muse, mutect2, varscan2
- SVOPL | c.1184C>T p.A395V (on ENST00000419765; = p.A243V on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as COSV55991732, COSV55994752; called by muse, mutect2, varscan2
- SYCP1 | c.2886G>T p.M962I | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV65698044, COSV65701673; called by muse, mutect2, varscan2
- SYNJ1 | c.4128G>T p.K1376N | Missense Mutation (SNP) | VAF 77/243 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.046); catalogued as COSV59149416; called by muse, mutect2, varscan2
- SYNPO | c.1481del p.G494Afs*11 (on ENST00000394243 / NM_001166208.2; = p.G250Afs*11 on NM_007286.6) | Frame Shift Del (DEL) | VAF 22/65 reads (34%) | catalogued as COSV56939890; called by mutect2, pindel, varscan2
- SYP | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 11/222 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54295424; called by muse, mutect2
- TAB3 | c.130C>T p.R44* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as rs770163638, COSV55835553; called by muse, mutect2, varscan2
- TAGLN2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV57422426; called by muse, mutect2, varscan2
- TAGLN3 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 32/129 reads (25%) | catalogued as rs1489005084, COSV56328041; called by muse, mutect2, varscan2
- TAS1R1 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs776804403, COSV60228325; called by muse, mutect2, varscan2
- TBC1D2B | c.2222C>A p.A741D | Missense Mutation (SNP) | VAF 81/259 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56042523; called by muse, mutect2, varscan2
- TBC1D9B | c.786G>T p.K262N | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.174); catalogued as COSV62282117; called by muse, varscan2
- TBX3 | c.1949C>A p.P650Q (on ENST00000257566 / NM_016569.4; = p.P630Q on NM_005996.4) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV57470876, COSV57473091; called by muse, mutect2, varscan2
- TDRD10 | c.651G>A p.E217= | Splice Region (SNP) | VAF 79/200 reads (40%) | catalogued as rs1035073246, COSV52725300; called by muse, mutect2, varscan2
- THBS1 | c.3365+2T>C p.X1122_splice | Splice Site (SNP) | VAF 67/195 reads (34%) | catalogued as COSV52952490; called by muse, mutect2, varscan2
- THSD7A | c.3908G>A p.G1303D | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV69855787; called by muse, mutect2, varscan2
- THSD7B | c.2420C>A p.P807H | Missense Mutation (SNP) | VAF 90/258 reads (35%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.754); catalogued as COSV55693156; called by muse, mutect2, varscan2
- TLN1 | c.6703C>T p.R2235* | Nonsense Mutation (SNP) | VAF 8/108 reads (7%) | catalogued as COSV59208017; called by muse, mutect2
- TMEM161B | c.52A>T p.M18L | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV56931255; called by muse, mutect2, varscan2
- TMEM79 | c.487dup p.R163Pfs*9 | Frame Shift Ins (INS) | VAF 11/30 reads (37%) | catalogued as rs780694092; called by mutect2, varscan2
- TMEM87B | c.848T>C p.L283S | Missense Mutation (SNP) | VAF 10/292 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV51715526; called by muse, mutect2
- TMX1 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 115/364 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs981072846, COSV63284867; called by muse, mutect2, varscan2
- TNFAIP1 | c.376-1G>T p.X126_splice | Splice Site (SNP) | VAF 36/96 reads (38%) | catalogued as COSV56876821; called by muse, mutect2, varscan2
- TNKS1BP1 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs768422961, COSV64100847; called by muse, mutect2
- TNPO1 | c.1055C>T p.T352M | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs1234511668, COSV61520501; called by muse, mutect2, varscan2
- TOP2B | c.3922_3924del p.K1308del (on ENST00000264331 / NM_001330700.2; = p.K1303del on NM_001068.3) | In Frame Del (DEL) | VAF 41/114 reads (36%) | catalogued as rs781031811; called by pindel, varscan2
- TREM1 | c.557C>A p.P186H | Missense Mutation (SNP) | VAF 143/443 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55148655; called by muse, mutect2, varscan2
- TRERF1 | c.1885G>A p.E629K | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as rs1458756658, COSV61671207; called by muse, mutect2, varscan2
- TRIM35 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as rs1326812007, COSV57757945; called by muse, mutect2, varscan2
- TRMT12 | c.117G>T p.R39S | Missense Mutation (SNP) | VAF 73/204 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV60777174; called by muse, mutect2, varscan2
- TRPA1 | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as COSV51563456; called by muse, mutect2, varscan2
- TSC22D1 | c.3146del p.P1049Lfs*38 (on ENST00000458659 / NM_183422.4; = p.P120Lfs*38 on NM_006022.4) | Frame Shift Del (DEL) | VAF 18/43 reads (42%) | catalogued as rs762485832; called by mutect2, pindel, varscan2
- TTLL3 | c.1870G>A p.A624T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.086); catalogued as COSV59614592; called by muse, mutect2, varscan2
- TULP4 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1562516582, COSV65576239; called by muse, mutect2, varscan2
- TXLNB | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 96/267 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64444236; called by muse, mutect2, varscan2
- TYRP1 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV66358019; called by muse, mutect2, varscan2
- UBASH3B | c.602-1del p.X201_splice | Splice Site (DEL) | VAF 89/258 reads (34%) | catalogued as COSV52495758; called by mutect2, pindel, varscan2
- UNC13C | c.4202C>A p.A1401D | Missense Mutation (SNP) | VAF 75/257 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.383); catalogued as COSV52879365; called by muse, mutect2, varscan2
- UNK | c.2308C>A p.L770I | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV52884984; called by muse, mutect2, varscan2
- UPB1 | c.971G>A p.S324N | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV58113885; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 23/73 reads (32%) | catalogued as rs767420916; called by mutect2, varscan2
- UQCRFS1 | c.793T>C p.F265L | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV59184973; called by muse, mutect2, varscan2
- USF3 | c.3773C>T p.A1258V | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs765316202, COSV57073718; called by muse, mutect2, varscan2
- USP30 | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 39/279 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV57449491; called by muse, mutect2, varscan2
- USP35 | c.2725G>C p.V909L | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV60866269, COSV60868337; called by muse, mutect2, varscan2
- USP5 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 65/233 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.257); catalogued as COSV57537556; called by muse, mutect2, varscan2
- UTP20 | c.392del p.L131* | Frame Shift Del (DEL) | VAF 78/228 reads (34%) | catalogued as rs761528888; called by mutect2, varscan2
- VMP1 | c.632C>A p.A211E | Missense Mutation (SNP) | VAF 86/191 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51868115; called by muse, mutect2, varscan2
- VPS41 | c.394G>A p.V132M | Missense Mutation (SNP) | VAF 84/209 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as rs1443015568, COSV56070401; called by muse, mutect2, varscan2
- WIPF2 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs781272623, COSV60273863; called by muse, mutect2, varscan2
- XKR6 | c.1189A>G p.M397V | Missense Mutation (SNP) | VAF 80/185 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV58656572; called by muse, mutect2, varscan2
- XPNPEP1 | c.363C>A p.Y121* | Nonsense Mutation (SNP) | VAF 100/293 reads (34%) | catalogued as COSV59168463; called by muse, mutect2, varscan2
- XRCC3 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs778439328, COSV57977146; called by muse, mutect2, varscan2
- ZBTB21 | c.1169G>T p.S390I | Missense Mutation (SNP) | VAF 69/178 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.05); catalogued as COSV60404322; called by muse, mutect2, varscan2
- ZC3H3 | c.302del p.G101Afs*102 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | catalogued as rs760469533; called by mutect2, varscan2
- ZNF106 | c.1444del p.S482Pfs*33 | Frame Shift Del (DEL) | VAF 90/262 reads (34%) | catalogued as rs1198467282, COSV55516091; called by mutect2, varscan2
- ZNF184 | c.668A>G p.K223R | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV53004451, COSV53005098; called by muse, mutect2, varscan2
- ZNF236 | c.1994C>T p.A665V | Missense Mutation (SNP) | VAF 69/210 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53489616; called by muse, mutect2, varscan2
- ZNF292 | c.5822A>C p.Q1941P | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.986); catalogued as COSV60536837; called by muse, mutect2, varscan2
- ZNF292 | c.6145del p.S2049Vfs*11 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | catalogued as rs764995318; called by mutect2, varscan2
- ZNF430 | c.365G>A p.G122D | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs1355880085, COSV55110171; called by muse, mutect2, varscan2
- ZNF502 | c.1326G>C p.K442N | Missense Mutation (SNP) | VAF 61/210 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56073810, COSV99939741; called by muse, mutect2, varscan2
- ZNF521 | c.2996G>A p.S999N | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.723); catalogued as rs115805119, COSV64127613; called by muse, mutect2, varscan2
- ZNF582 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.048); catalogued as rs1324682117, COSV56731464; called by muse, mutect2, varscan2
- ZNF598 | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV70910070; called by muse, mutect2, varscan2
- ZNF644 | c.871del p.R291Efs*7 | Frame Shift Del (DEL) | VAF 30/115 reads (26%) | catalogued as rs749473342; called by mutect2, varscan2
- ZNF791 | c.220G>T p.G74C | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.299); catalogued as COSV58481173; called by muse, mutect2, varscan2
- ZXDA | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV62388125; called by muse, mutect2
- AC007040.2 | c.423del p.F141Lfs*22 | Frame Shift Del (DEL) | VAF 26/90 reads (29%) | called by mutect2, pindel, varscan2
- ACTB | c.1096_1124del p.G366Lfs*5 | Frame Shift Del (DEL) | VAF 12/137 reads (9%) | called by mutect2, pindel
- ADAMTSL1 | c.3464del p.G1155Efs*42 | Frame Shift Del (DEL) | VAF 19/61 reads (31%) | called by mutect2, pindel, varscan2
- AHNAK | c.9064del p.M3022Cfs*4 | Frame Shift Del (DEL) | VAF 35/134 reads (26%) | called by mutect2, pindel, varscan2
- ATE1 | c.989del p.P330Lfs*26 | Frame Shift Del (DEL) | VAF 26/78 reads (33%) | called by mutect2, pindel, varscan2
- AUNIP | c.863del p.F288Sfs*22 | Frame Shift Del (DEL) | VAF 54/140 reads (39%) | called by mutect2, pindel, varscan2
- BOD1L1 | c.1003_1004del p.K335Efs*8 | Frame Shift Del (DEL) | VAF 68/210 reads (32%) | called by mutect2, pindel, varscan2
- C17orf98 | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 89/221 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 58/172 reads (34%) | called by pindel, varscan2
- CNNM2 | c.1531del p.L511* | Frame Shift Del (DEL) | VAF 73/247 reads (30%) | called by mutect2, pindel, varscan2
- COL27A1 | c.197del p.G66Efs*37 | Frame Shift Del (DEL) | VAF 17/46 reads (37%) | called by mutect2, pindel, varscan2
- DDX17 | c.488del p.G163Efs*20 | Frame Shift Del (DEL) | VAF 94/271 reads (35%) | called by mutect2, pindel, varscan2
- DNAH3 | c.6722del p.L2241* | Frame Shift Del (DEL) | VAF 27/256 reads (11%) | called by mutect2, pindel, varscan2
- DOCK5 | c.4705-3_4706delinsAGGCT p.X1569_splice | Splice Site (ONP) | VAF 17/117 reads (15%) | called by pindel, varscan2*
- EEF1D | c.1del p.M1? | Frame Shift Del (DEL) | VAF 45/166 reads (27%) | called by mutect2, pindel, varscan2
- EIF2A | c.818del p.N273Mfs*7 | Frame Shift Del (DEL) | VAF 28/91 reads (31%) | called by mutect2, pindel, varscan2
- EPHA2 | c.1379del p.P460Rfs*33 | Frame Shift Del (DEL) | VAF 17/57 reads (30%) | called by mutect2, pindel, varscan2
- FANCB | c.296del p.N99Ifs*12 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | called by mutect2, pindel, varscan2
- IFIH1 | c.2994del p.K998Nfs*7 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | called by mutect2, pindel, varscan2
- ITPR2 | c.5509del p.R1837Gfs*7 | Frame Shift Del (DEL) | VAF 37/373 reads (10%) | called by mutect2, pindel
- JAG1 | c.1160del p.G387Afs*25 | Frame Shift Del (DEL) | VAF 35/98 reads (36%) | called by mutect2, pindel, varscan2
- JAG2 | c.764del p.G255Dfs*54 | Frame Shift Del (DEL) | VAF 22/70 reads (31%) | called by mutect2, pindel, varscan2
- KIF20B | c.3395del p.N1132Mfs*11 (on ENST00000371728 / NM_001284259.2; = p.N1092Mfs*11 on NM_016195.4) | Frame Shift Del (DEL) | VAF 11/26 reads (42%) | called by mutect2, pindel, varscan2
- LRRC7 | c.3192del p.V1065Sfs*16 (on ENST00000651989 / NM_001370785.2; = p.V1032Sfs*16 on NM_001330635.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 17/61 reads (28%) | called by mutect2, pindel, varscan2
- MBTPS1 | c.1218del p.C407Afs*21 | Frame Shift Del (DEL) | VAF 12/115 reads (10%) | called by mutect2, pindel, varscan2
- MUC5B | c.10568del p.P3523Lfs*41 | Frame Shift Del (DEL) | VAF 96/290 reads (33%) | called by mutect2, pindel, varscan2
- NBEA | c.3362dup p.N1121Kfs*2 | Frame Shift Ins (INS) | VAF 64/177 reads (36%) | called by mutect2, varscan2
- NCEH1 | c.755del p.N252Ifs*8 (on ENST00000538775; = p.N212Ifs*8 on NM_020792.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 58/167 reads (35%) | called by mutect2, pindel, varscan2
- PAXBP1 | c.1460_1462del p.R487del | In Frame Del (DEL) | VAF 38/110 reads (35%) | called by pindel, varscan2
- PC | c.3002_3004del p.E1001del | In Frame Del (DEL) | VAF 44/148 reads (30%) | called by pindel, varscan2
- PCDHA12 | c.558del p.D187Ifs*8 | Frame Shift Del (DEL) | VAF 28/79 reads (35%) | called by mutect2, pindel, varscan2
- PGAM5 | c.540del p.I181Sfs*83 (on ENST00000498926 / NM_001170543.2; = p.I181Sfs*107 on NM_138575.4) | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | called by mutect2, pindel, varscan2
- PHACTR2 | c.587del p.N196Ifs*80 | Frame Shift Del (DEL) | VAF 56/158 reads (35%) | called by mutect2, varscan2
- PNISR | c.1491dup p.E498Rfs*3 | Frame Shift Ins (INS) | VAF 90/270 reads (33%) | called by mutect2, varscan2
- PSMB6 | c.422_424del p.E141del | In Frame Del (DEL) | VAF 36/104 reads (35%) | called by pindel, varscan2
- PTCHD1 | c.745dup p.M249Nfs*78 | Frame Shift Ins (INS) | VAF 64/210 reads (30%) | called by mutect2, pindel, varscan2
- RASGRP4 | c.1809del p.G604Efs*57 | Frame Shift Del (DEL) | VAF 61/197 reads (31%) | called by mutect2, pindel, varscan2
- RIPK1 | c.867_870del p.Y289* | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | called by pindel, varscan2
- RPS6KA1 | c.2137del p.Q713Sfs*2 | Frame Shift Del (DEL) | VAF 90/257 reads (35%) | called by mutect2, pindel, varscan2
- RPS6KL1 | c.1032del p.L345Sfs*12 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, varscan2
- SEZ6L | c.2865del p.N956Tfs*37 | Frame Shift Del (DEL) | VAF 64/195 reads (33%) | called by mutect2, pindel, varscan2
- SH3PXD2B | c.330dup p.Y111Lfs*6 | Frame Shift Ins (INS) | VAF 55/147 reads (37%) | called by mutect2, pindel, varscan2
- SLC34A1 | c.1862del p.P621Lfs*61 | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | called by mutect2, pindel, varscan2
- STOML1 | c.298del p.Q100Rfs*20 | Frame Shift Del (DEL) | VAF 41/149 reads (28%) | called by mutect2, pindel, varscan2
- SUGP2 | c.763del p.I255Yfs*4 | Frame Shift Del (DEL) | VAF 108/293 reads (37%) | called by mutect2, varscan2
- TACC2 | c.6446del p.P2149Qfs*2 (on ENST00000334433; = p.P227Qfs*2 on NM_006997.4) | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | called by mutect2, pindel, varscan2
- TASOR | c.1686del p.F562Lfs*21 (on ENST00000355628 / NM_001365636.2; = p.F166Lfs*21 on NM_015224.3) | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | called by mutect2, pindel, varscan2
- TPH1 | c.750dup p.H251Sfs*23 | Frame Shift Ins (INS) | VAF 45/174 reads (26%) | called by mutect2, pindel, varscan2
- TRAV10 | c.146G>A p.S49N | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- UBASH3A | c.730del p.H244Tfs*38 | Frame Shift Del (DEL) | VAF 39/126 reads (31%) | called by mutect2, pindel, varscan2
- UBR4 | c.8406del p.M2803Cfs*16 | Frame Shift Del (DEL) | VAF 64/189 reads (34%) | called by mutect2, pindel, varscan2
- USP47 | c.3360del p.G1121Efs*22 (on ENST00000399455 / NM_001372095.1; = p.G1033Efs*22 on NM_017944.4 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 21/61 reads (34%) | called by mutect2, pindel, varscan2
- ZNF536 | c.392del p.P131Rfs*83 | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | called by mutect2, pindel, varscan2
- ZNF646 | c.18del p.S7Hfs*88 | Frame Shift Del (DEL) | VAF 26/87 reads (30%) | called by mutect2, pindel, varscan2
- ACADSB | c.780C>A p.T260= | Silent (SNP) | VAF 52/156 reads (33%) | catalogued as COSV62550815; called by muse, mutect2, varscan2
- ADAMTS20 | c.213G>A p.L71= | Silent (SNP) | VAF 53/153 reads (35%) | catalogued as COSV67132632; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4608G>A p.Q1536= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV65878051; called by muse, mutect2, varscan2
- ADCY6 | c.3132C>T p.N1044= | Silent (SNP) | VAF 53/154 reads (34%) | catalogued as rs1488414489, COSV57168228; called by muse, mutect2, varscan2
- ADGRE5 | c.498C>T p.S166= | Silent (SNP) | VAF 61/176 reads (35%) | catalogued as rs771227562, COSV54411588; called by muse, mutect2, varscan2
- AGPS | c.447C>A p.S149= | Silent (SNP) | VAF 27/110 reads (25%) | catalogued as COSV51564754; called by muse, mutect2, varscan2
- ALPI | c.1146C>A p.S382= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as COSV55014871, COSV55015019; called by muse, mutect2, varscan2
- ARHGAP12 | c.333T>C p.P111= | Silent (SNP) | VAF 41/113 reads (36%) | catalogued as COSV60963700; called by muse, mutect2, varscan2
- ATAD2B | c.3582T>C p.N1194= | Silent (SNP) | VAF 87/261 reads (33%) | catalogued as COSV53199598; called by muse, mutect2, varscan2
- ATF6B | c.549C>T p.A183= | Silent (SNP) | VAF 79/189 reads (42%) | catalogued as rs984794162, COSV64351952; called by muse, mutect2, varscan2
- ATG9B | c.1755G>A p.A585= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs764819392, COSV52490573; called by muse, varscan2
- ATP2A1 | c.1260C>T p.C420= | Silent (SNP) | VAF 39/123 reads (32%) | catalogued as COSV63921323; called by muse, mutect2, varscan2
- ATXN3 | c.954G>A p.R318= | Silent (SNP) | VAF 59/151 reads (39%) | catalogued as COSV61495631; called by muse, mutect2, varscan2
- AUTS2 | c.2406G>A p.S802= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs748478664, COSV61405729; called by muse, mutect2, varscan2
- BARHL2 | c.594G>A p.R198= | Silent (SNP) | VAF 49/132 reads (37%) | catalogued as rs1194316922, COSV100966052, COSV64981386; called by muse, mutect2, varscan2
- BIRC6 | c.3309T>C p.H1103= | Silent (SNP) | VAF 74/279 reads (27%) | catalogued as COSV70199981; called by muse, mutect2, varscan2
- BPIFB1 | c.340C>T p.L114= | Silent (SNP) | VAF 51/129 reads (40%) | catalogued as rs1351068010, COSV53606816; called by muse, mutect2, varscan2
- CACNA1F | c.5616G>A p.L1872= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as rs1557104705, COSV59904852; called by muse, mutect2, varscan2
- CACNA2D2 | c.975C>T p.D325= | Silent (SNP) | VAF 50/136 reads (37%) | catalogued as COSV56564163; called by muse, mutect2, varscan2
- CAMKV | c.423C>T p.I141= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as rs748592570, COSV56555938; called by muse, mutect2, varscan2
- CAMSAP1 | c.4005G>A p.A1335= | Silent (SNP) | VAF 40/113 reads (35%) | catalogued as COSV56723350; called by muse, mutect2, varscan2
- CARNS1 | c.2340C>T p.G780= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs190057931; called by muse, mutect2, varscan2
- CBL | c.279G>A p.Q93= | Silent (SNP) | VAF 72/175 reads (41%) | catalogued as COSV50639280; called by muse, mutect2, varscan2
- CCDC121 | c.813C>A p.T271= | Silent (SNP) | VAF 13/274 reads (5%) | catalogued as COSV53115145, COSV99270138; called by muse, mutect2
- CD207 | c.903C>A p.P301= | Silent (SNP) | VAF 139/363 reads (38%) | catalogued as COSV69652177; called by muse, mutect2, varscan2
- CFHR4 | c.1050C>T p.S350= (on ENST00000367416 / NM_001201551.2; = p.S104= on NM_006684.5) | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs772251666, COSV52229748; called by muse, mutect2, varscan2
- CGA | c.45G>A p.L15= | Silent (SNP) | VAF 22/185 reads (12%) | catalogued as COSV63644484; called by muse, varscan2
- CHRNA10 | c.1113G>A p.S371= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as rs768856023, COSV51704945; called by muse, mutect2, varscan2
- CLCN4 | c.1518C>T p.P506= | Silent (SNP) | VAF 42/110 reads (38%) | catalogued as rs749694905, COSV66466773; ClinVar: likely benign; called by muse, mutect2, varscan2
- CMIP | c.1966C>T p.L656= (on ENST00000537098 / NM_198390.2; = p.L562= on NM_030629.3) | Silent (SNP) | VAF 39/103 reads (38%) | catalogued as rs749496229, COSV67698573; called by muse, mutect2, varscan2
- CTNNA3 | c.927T>C p.S309= | Silent (SNP) | VAF 16/308 reads (5%) | catalogued as COSV65588084; called by muse, mutect2
- DBT | c.75A>G p.T25= | Silent (SNP) | VAF 38/133 reads (29%) | catalogued as COSV64495561; called by muse, mutect2, varscan2
- DNAAF1 | c.804C>T p.V268= | Silent (SNP) | VAF 78/199 reads (39%) | catalogued as COSV57577480; called by muse, mutect2, varscan2
- DOK2 | c.765G>A p.P255= | Silent (SNP) | VAF 84/212 reads (40%) | catalogued as rs749995504, COSV52388508; called by muse, mutect2, varscan2
- EHBP1 | c.3279G>A p.A1093= | Silent (SNP) | VAF 57/167 reads (34%) | catalogued as rs768976199, COSV50421355; called by muse, mutect2, varscan2
- EHD2 | c.1144C>T p.L382= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs1482522819, COSV54408682; called by muse, mutect2, varscan2
- EPHB2 | c.3048C>T p.D1016= | Silent (SNP) | VAF 58/164 reads (35%) | catalogued as rs763473046, COSV65862964; called by mutect2, varscan2
- ESYT3 | c.880C>T p.L294= | Silent (SNP) | VAF 74/224 reads (33%) | catalogued as COSV56680592; called by muse, mutect2, varscan2
- FAM163A | c.285C>T p.C95= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV59203875; called by muse, mutect2, varscan2
- FAM90A1 | c.453G>A p.P151= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs771226962, COSV56710105; called by muse, mutect2
- FAXDC2 | c.456C>A p.P152= | Silent (SNP) | VAF 57/178 reads (32%) | catalogued as COSV58172447; called by muse, mutect2, varscan2
- FERD3L | c.300C>T p.Y100= | Silent (SNP) | VAF 11/207 reads (5%) | catalogued as rs1410313015, COSV51762957; called by muse, mutect2
- FIZ1 | c.453C>T p.C151= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV55607954; called by muse, mutect2, varscan2
- FKBPL | c.871C>A p.R291= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as COSV64322540; called by muse, mutect2, varscan2
- FRRS1 | c.1797C>T p.I599= | Silent (SNP) | VAF 51/156 reads (33%) | catalogued as COSV54922442; called by muse, mutect2, varscan2
- FTMT | c.270G>A p.A90= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV58419657, COSV58420171; called by muse, mutect2, varscan2
- GGCX | c.1452T>C p.P484= | Silent (SNP) | VAF 41/109 reads (38%) | catalogued as COSV52088582; called by muse, mutect2, varscan2
- GPC1 | c.1161C>T p.R387= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as rs781129332, COSV50862996; called by muse, mutect2, varscan2
- GRIN2B | c.3669C>T p.H1223= | Silent (SNP) | VAF 46/137 reads (34%) | catalogued as COSV74206120; called by muse, mutect2, varscan2
- HMGCR | c.1047A>G p.S349= | Silent (SNP) | VAF 45/132 reads (34%) | catalogued as COSV55315994; called by muse, mutect2, varscan2
- HYDIN | c.12333G>A p.K4111= | Silent (SNP) | VAF 56/167 reads (34%) | catalogued as COSV66639347; called by muse, mutect2, varscan2
- IGHG2 | c.249C>T p.C83= | Silent (SNP) | VAF 69/487 reads (14%) | called by muse, mutect2, varscan2
- IL17RA | c.1806C>T p.D602= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs1222021723, COSV60053859; called by mutect2, varscan2
- ILDR1 | c.525C>A p.I175= | Silent (SNP) | VAF 60/187 reads (32%) | catalogued as COSV56550434, COSV56553697; called by muse, mutect2, varscan2
- INTS13 | c.1842G>A p.L614= | Silent (SNP) | VAF 95/254 reads (37%) | catalogued as COSV53902901; called by muse, mutect2, varscan2
- ITGA5 | c.2757G>A p.L919= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as COSV53218174; called by muse, mutect2, varscan2
- IWS1 | c.405T>C p.N135= | Silent (SNP) | VAF 57/185 reads (31%) | catalogued as COSV54868919; called by muse, mutect2, varscan2
- JAK3 | c.2283C>A p.A761= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV71686094, COSV71686994; called by muse, mutect2, varscan2
- KCNJ13 | c.534A>G p.V178= | Silent (SNP) | VAF 72/193 reads (37%) | catalogued as COSV52085335; called by muse, mutect2, varscan2
- KCNT2 | c.18C>T p.S6= | Silent (SNP) | VAF 100/326 reads (31%) | catalogued as COSV54080085; called by muse, mutect2, varscan2
- LARP4 | c.2038C>A p.R680= | Silent (SNP) | VAF 42/122 reads (34%) | catalogued as COSV53323126, COSV53323148; called by muse, mutect2, varscan2
- LCN15 | c.216C>T p.H72= | Silent (SNP) | VAF 31/104 reads (30%) | catalogued as rs775998183, COSV60210356; called by muse, mutect2, varscan2
- LHFPL2 | c.645G>A p.Q215= | Silent (SNP) | VAF 56/218 reads (26%) | catalogued as COSV66714812; called by muse, mutect2, varscan2
- LHX5 | c.606G>A p.T202= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV55663006; called by muse, mutect2, varscan2
- LTF | c.1941G>A p.P647= | Silent (SNP) | VAF 71/190 reads (37%) | catalogued as rs574575140, COSV51608600; called by muse, mutect2, varscan2
- MAST4 | c.4503C>T p.R1501= (on ENST00000403625 / NM_001164664.2; = p.R1312= on NM_015183.3) | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs1280960501, COSV55118471; called by mutect2, varscan2
- MEP1A | c.2145C>T p.H715= | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as rs753884321, COSV57920392; called by muse, mutect2, varscan2
- MICALL2 | c.867T>C p.P289= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV52516113; called by muse, mutect2, varscan2
- MLNR | c.969C>T p.N323= | Silent (SNP) | VAF 75/230 reads (33%) | catalogued as rs1294658889, COSV54532907; called by muse, mutect2, varscan2
- MROH1 | c.2718C>T p.S906= | Silent (SNP) | VAF 49/165 reads (30%) | called by muse, mutect2, varscan2
- NCKAP1L | c.3327T>C p.P1109= | Silent (SNP) | VAF 120/297 reads (40%) | catalogued as COSV53207589; called by muse, mutect2, varscan2
- NCOA6 | c.5982C>A p.A1994= | Silent (SNP) | VAF 59/166 reads (36%) | catalogued as COSV62864262; called by muse, mutect2, varscan2
- NFASC | c.3576G>A p.V1192= (on ENST00000339876 / NM_001378329.1; = p.V1121= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 109/306 reads (36%) | catalogued as COSV58366793; called by muse, mutect2, varscan2
- NID1 | c.987C>A p.P329= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as COSV51621162, COSV99938075; called by muse, mutect2, varscan2
- NOTCH2NLA | c.240C>T p.G80= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs782227718, COSV61250028; called by mutect2, varscan2
- OR11L1 | c.45A>G p.L15= | Silent (SNP) | VAF 46/138 reads (33%) | catalogued as COSV63314726; called by muse, mutect2, varscan2
- OR6B3 | c.414G>A p.P138= | Silent (SNP) | VAF 32/130 reads (25%) | catalogued as rs772530124, COSV100097023; called by muse, mutect2
- OSBPL7 | c.36T>C p.P12= | Silent (SNP) | VAF 47/156 reads (30%) | catalogued as COSV50109272; called by muse, mutect2, varscan2
- OTOGL | c.5826T>C p.C1942= (on ENST00000547103; = p.C1933= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 32/103 reads (31%) | catalogued as COSV54017569; called by muse, mutect2, varscan2
- PCDHA3 | c.183G>A p.P61= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV65365877; called by muse, mutect2, varscan2
- PCDHA7 | c.777G>A p.T259= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100971753; called by mutect2, varscan2
- PCSK6 | c.2787C>T p.C929= | Silent (SNP) | VAF 52/181 reads (29%) | catalogued as COSV61853754; called by muse, mutect2, varscan2
- PITX1 | c.180C>T p.R60= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV54762352; called by muse, mutect2, varscan2
- PRCP | c.408C>T p.F136= | Silent (SNP) | VAF 52/133 reads (39%) | catalogued as COSV57289094; called by muse, mutect2, varscan2
- PROX1 | c.1029G>A p.P343= | Silent (SNP) | VAF 70/182 reads (38%) | catalogued as rs768687981, COSV54779541; called by muse, mutect2, varscan2
- PTPN18 | c.822C>T p.A274= | Silent (SNP) | VAF 72/181 reads (40%) | catalogued as rs1214739114, COSV51559180; called by muse, mutect2, varscan2
- PVRIG | c.279A>G p.P93= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs745763591, COSV52781368; called by muse, varscan2
- PXN | c.1356C>T p.P452= (on ENST00000228307 / NM_001080855.3; = p.P418= on NM_002859.4) | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as rs558454285, COSV57219110; called by muse, mutect2, varscan2
- RAE1 | c.444C>T p.S148= | Silent (SNP) | VAF 137/357 reads (38%) | catalogued as COSV64798011; called by muse, mutect2, varscan2
- RANBP17 | c.1392C>T p.F464= | Silent (SNP) | VAF 101/321 reads (31%) | catalogued as rs373712608, COSV66651013; called by muse, mutect2, varscan2
- RRBP1 | c.3840G>A p.A1280= (on ENST00000377813 / NM_001365613.2; = p.A847= on NM_004587.3) | Silent (SNP) | VAF 38/103 reads (37%) | catalogued as rs371306215; called by muse, mutect2, varscan2
- SAFB2 | c.405C>T p.D135= | Silent (SNP) | VAF 69/213 reads (32%) | catalogued as rs756499003, COSV53042771; called by muse, mutect2, varscan2
- SCFD2 | c.1575A>G p.S525= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as COSV66372204; called by muse, mutect2, varscan2
- SDHA | c.1935C>A p.I645= | Silent (SNP) | VAF 67/235 reads (29%) | catalogued as COSV53768838; called by muse, mutect2, varscan2
- SDK1 | c.3846C>T p.N1282= | Silent (SNP) | VAF 61/166 reads (37%) | catalogued as rs139165481, COSV67371405; called by muse, mutect2, varscan2
- SERPINA4 | c.1185C>T p.H395= | Silent (SNP) | VAF 42/154 reads (27%) | catalogued as rs201404679, COSV54070197; called by muse, mutect2, varscan2
- SLC16A3 | c.228G>A p.P76= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as rs777014873, COSV66429591; called by muse, mutect2, varscan2
- SLC22A14 | c.1041C>A p.T347= | Silent (SNP) | VAF 54/146 reads (37%) | catalogued as rs377398495, COSV56197934; called by muse, mutect2, varscan2
- SLC25A37 | c.75C>T p.G25= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV51564323; called by muse, mutect2, varscan2
- SLC43A2 | c.324C>T p.I108= | Silent (SNP) | VAF 47/134 reads (35%) | catalogued as rs770113579, COSV56769413; called by muse, mutect2, varscan2
- SLC4A3 | c.3546C>A p.P1182= | Silent (SNP) | VAF 43/137 reads (31%) | catalogued as COSV56094352, COSV99813307; called by muse, mutect2, varscan2
- SLX4 | c.2145G>A p.P715= | Silent (SNP) | VAF 53/183 reads (29%) | catalogued as rs773209008, COSV53564645; called by muse, mutect2, varscan2
- SMC5 | c.3279C>T p.R1093= | Silent (SNP) | VAF 47/110 reads (43%) | catalogued as COSV63193269; called by muse, mutect2, varscan2
- SNPH | c.180G>A p.L60= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as COSV67870776; called by muse, mutect2, varscan2
- SPAG9 | c.2484A>G p.T828= (on ENST00000262013 / NM_001130528.3; = p.T814= on NM_003971.6) | Silent (SNP) | VAF 86/220 reads (39%) | catalogued as COSV56236534; called by muse, mutect2, varscan2
- SPTBN1 | c.6456C>T p.N2152= | Silent (SNP) | VAF 38/116 reads (33%) | catalogued as rs528849120, COSV61689236; called by muse, mutect2, varscan2
- SRSF1 | c.441A>G p.V147= | Silent (SNP) | VAF 67/167 reads (40%) | catalogued as COSV51965105; called by muse, mutect2, varscan2
- TACR3 | c.583C>T p.L195= | Silent (SNP) | VAF 48/179 reads (27%) | catalogued as COSV59202270; called by muse, mutect2, varscan2
- TAF8 | c.423C>T p.P141= | Silent (SNP) | VAF 55/163 reads (34%) | catalogued as COSV65896225; called by muse, mutect2, varscan2
- TBC1D25 | c.1185G>A p.L395= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV65123841; called by muse, mutect2, varscan2
- TEKT5 | c.114C>A p.P38= | Silent (SNP) | VAF 32/90 reads (36%) | catalogued as COSV51589318; called by muse, mutect2, varscan2
- TGM6 | c.303C>T p.L101= | Silent (SNP) | VAF 77/205 reads (38%) | catalogued as rs757250219, COSV52479048; ClinVar: likely benign; called by muse, mutect2, varscan2
- THBS2 | c.2085G>A p.S695= | Silent (SNP) | VAF 64/184 reads (35%) | catalogued as rs751745322, COSV64679315; called by muse, mutect2, varscan2
- TMEM131L | c.1854C>T p.S618= | Silent (SNP) | VAF 126/347 reads (36%) | catalogued as COSV53645148; called by muse, mutect2, varscan2
- TMEM179 | c.507G>A p.Q169= | Silent (SNP) | VAF 68/161 reads (42%) | catalogued as COSV58795544; called by muse, mutect2, varscan2
- TRPM4 | c.1662C>T p.L554= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as rs772790473, COSV53263520; called by muse, mutect2, varscan2
- TSHZ1 | c.646C>T p.L216= (on ENST00000580243 / NM_001308210.2; = p.L171= on NM_005786.6) | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV59010545; called by muse, mutect2, varscan2
- TTC21B | c.3202T>C p.L1068= | Silent (SNP) | VAF 50/154 reads (32%) | catalogued as COSV54631236; called by muse, mutect2, varscan2
- TUBGCP3 | c.1635G>A p.L545= | Silent (SNP) | VAF 39/121 reads (32%) | catalogued as COSV56187326; called by muse, mutect2, varscan2
- UPF1 | c.1341G>A p.S447= (on ENST00000599848 / NM_001297549.2; = p.S436= on NM_002911.4) | Silent (SNP) | VAF 47/121 reads (39%) | catalogued as rs137917420, COSV99439339; called by muse, mutect2, varscan2
- USP9X | c.2394G>T p.T798= | Silent (SNP) | VAF 75/211 reads (36%) | catalogued as COSV61069728; called by muse, mutect2, varscan2
- UTP25 | c.1200C>T p.P400= | Silent (SNP) | VAF 99/325 reads (30%) | catalogued as rs776708760, COSV71965986; called by muse, mutect2, varscan2
- UTRN | c.6270G>A p.R2090= | Silent (SNP) | VAF 16/140 reads (11%) | catalogued as rs374804526; called by muse, mutect2, varscan2
- UTS2R | c.120C>A p.T40= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs377274020, COSV57453005; called by muse, mutect2, varscan2
- WWP1 | c.2217G>A p.L739= | Silent (SNP) | VAF 74/220 reads (34%) | catalogued as COSV55359760; called by muse, mutect2, varscan2
- ZBTB38 | c.2394T>C p.P798= | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as rs771013098, COSV58542158; called by muse, mutect2, varscan2
- ZBTB40 | c.2433C>A p.L811= | Silent (SNP) | VAF 42/101 reads (42%) | catalogued as COSV65145484; called by muse, mutect2, varscan2
- ZBTB7A | c.534C>T p.A178= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs1442124828, COSV59327486; called by muse, mutect2, varscan2
- ZNF286A | c.159C>T p.D53= | Silent (SNP) | VAF 10/176 reads (6%) | catalogued as COSV67844608; called by muse, mutect2
- ZNF331 | c.1050G>A p.T350= | Silent (SNP) | VAF 79/218 reads (36%) | catalogued as rs773068094, COSV53477242; called by muse, mutect2, varscan2
- ZNF510 | c.36G>A p.V12= | Silent (SNP) | VAF 64/207 reads (31%) | catalogued as COSV56297586; called by muse, mutect2, varscan2
- ZNF658 | c.312C>A p.I104= | Silent (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- ZSCAN25 | c.1611C>T p.H537= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs891727575, COSV53553226; called by muse, mutect2, varscan2
- ADPRHL1 | c.-2G>A | 5'UTR (SNP) | VAF 30/85 reads (35%) | catalogued as COSV100215110, COSV100215395; called by muse, mutect2, varscan2
- HERC2P3 | chr15:20457665 C>T | 5'Flank (SNP) | VAF 49/423 reads (12%) | called by muse, mutect2, varscan2
- ING1 | chr13:110712977 G>T | 5'Flank (SNP) | VAF 10/31 reads (32%) | catalogued as COSV58169592; called by muse, mutect2, varscan2
- KCNIP3 | c.182-27231C>G | Intron (SNP) | VAF 40/112 reads (36%) | catalogued as rs1190424315, COSV54669335; called by muse, mutect2, varscan2
- MIR337 | n.19del | RNA (DEL) | VAF 75/187 reads (40%) | called by mutect2, varscan2
- RMDN2 | c.453-21859T>G | Intron (SNP) | VAF 16/41 reads (39%) | catalogued as COSV52225628; called by muse, mutect2, varscan2
- TEX11 | c.-56del | 5'UTR (DEL) | VAF 52/154 reads (34%) | catalogued as rs772853520, COSV65467559; called by mutect2, varscan2
